Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A8EJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A8EJ-01A (Primary Tumor).

Collect date:

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

- "Biopsy of the cervix":

Invasive squamous cell carcinoma histological grade 3.

ICD-O-3

Carcinoma, squamous cell NOS
8070/3

Site Cervix NOS
C53.9

JW 11/21/13

Source: NCI Genomic Data Commons file f0594218-c6bb-4844-92e2-aa35ca30a7a9 (TCGA-VS-A8EJ.92D067E8-1E5A-46B6-90BD-4DF9782CCA32.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).